CPTAC case C3N-03783 — Gum — Squamous Cell Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Squamous Cell Neoplasms; Primary site: Gum. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/615a0ca9-8c35-4bbd-bdda-dce68e805839

Demographics
Sex at birth: male; Race: white; Year of birth: 1951; Vital status: Dead; Days to death: 952 days (2.6 years); Year of death: 2020; Cause of death: Cancer Related; Country of birth: Poland.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Gum, NOS; Site of resection or biopsy: Gum, NOS; Age at diagnosis: 67.1 years (24,500 days); Year of diagnosis: 2018; AJCC staging edition: 8th; AJCC clinical M: M0; AJCC pathologic T: T2; AJCC pathologic N: N2b; AJCC pathologic M: MX; AJCC pathologic stage: Stage IVA; Tumor grade: G1; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 952 days (2.6 years); Progression or recurrence: no; Days to last follow up: 952 days (2.6 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 2 cm; Lymph node involvement: Positive; Lymph nodes positive: 2; Lymph nodes tested: 7; Lymphatic invasion present: No; Margin status: Uninvolved; Perineural invasion present: No; Vascular invasion present: No.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (4 entries)
- Days to follow up: 253 days; Disease response: Tumor Free; Karnofsky performance status: 80; ECOG performance status: 1.
- Days to follow up: 739 days (2.0 years); Disease response: With Tumor; Karnofsky performance status: 60; ECOG performance status: 3.
- Days to follow up: 917 days (2.5 years); Disease response: Progressive Disease; Progression or recurrence: Yes; Days to recurrence: 721 days (2.0 years); Karnofsky performance status: 50; ECOG performance status: 2.
- Days to follow up: 952 days (2.6 years); Disease response: With Tumor; Karnofsky performance status: 50; ECOG performance status: 2.

Other clinical attributes
- Weight: 100 kg; Height: 176 cm; BMI: 32.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 50; Cigarettes per day: 20; Tobacco smoking onset year: 1968; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 54.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-03783-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Alveolar Ridge; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -2 days; Initial weight: 259 mg; Time between excision and freezing: 11 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-03783-21: Section location: Alveolar Ridge; Percent tumor nuclei: 80; Percent necrosis: 5.
- Sample C3N-03783-11: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Alveolar Ridge; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -2 days; Time between excision and freezing: 11 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-03783-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -2 days; Method of sample procurement: Blood Draw.
